Surgical pathology report (de-identified scan), TCGA case TCGA-2G-AAH7, project TCGA-TGCT (Testicular Germ Cell Tumors), specimen TCGA-2G-AAH7-01A (Primary Tumor).

Department of Pathology

Direct dial

Mobile:

Internal postal address

E-mail

Date

Concerning

Postal address

Street address

Summary pathology report

Right orchidectomy; seminoma; diameter 1,5 cm; no angio-invasion; no invasion of tunica albuginea.

Date of procurement (= date of orchidectomy):

pathologist

professor of pathology

ICD O.3

Seminoma NOS 9061/3

Site (R) Testis NOS C62.9

9/23/14

Source: NCI Genomic Data Commons file fe714259-3f8a-4734-bf13-ca6a8a6df41b (TCGA-2G-AAH7-01A.pdf), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).